Somatic mutation profile of tumor specimen TCGA-76-4926-01B (aliquot TCGA-76-4926-01B-01D-1486-08) from TCGA case TCGA-76-4926, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 68.7 years (25,085 days).
Specimen TCGA-76-4926-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e57c6f8-a1ed-4f4f-9c43-5d31e60275a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-76-4926-10A (Blood Derived Normal), aliquot TCGA-76-4926-10A-01D-1486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8755916d-6481-4ca2-a5f4-5c542c7e5c93

The open-access MAF lists 62 somatic variants for this specimen: 48 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 40, Silent 14, Frame Shift Del 3, Nonsense Mutation 2, Translation Start Site 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 26/726 reads (4%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51784086; called by muse, mutect2
- KIF26B | c.6071G>A p.R2024H | Missense Mutation (SNP) | VAF 31/94 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199933797, COSV63638897; called by muse, mutect2, varscan2
- AACS | c.1197_1198del p.H399Qfs*57 | Frame Shift Del (DEL) | VAF 36/142 reads (25%) | catalogued as rs772435620; called by pindel, varscan2
- ACE | c.3181G>A p.A1061T | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as rs773695336, COSV52004814; called by muse, mutect2
- ARNTL2 | c.575G>A p.G192D | Missense Mutation (SNP) | VAF 79/197 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754238582, COSV53824438; called by muse, mutect2, varscan2
- ATP11C | c.85A>G p.N29D | Missense Mutation (SNP) | VAF 104/129 reads (81%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as COSV59560875; called by muse, mutect2, varscan2
- BMPER | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 107/406 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1043861409, COSV51814238; called by muse, mutect2, varscan2
- CACNA1B | c.5903C>G p.S1968* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as COSV53118784; called by muse, mutect2, varscan2
- CD177 | c.478G>C p.D160H | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as COSV65121038; called by muse, mutect2, varscan2
- CEP250 | c.2099G>A p.R700H | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs377363130; called by muse, mutect2, varscan2
- CMYA5 | c.1594G>A p.V532I | Missense Mutation (SNP) | VAF 105/262 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773904463, COSV71404679; called by muse, mutect2, varscan2
- CYP11B2 | c.31G>A p.V11M | Missense Mutation (SNP) | VAF 130/329 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs574581657, COSV59995257; called by muse, mutect2, varscan2
- GPR137 | c.1032-2A>C p.X344_splice | Splice Site (SNP) | VAF 58/152 reads (38%) | catalogued as COSV57401468; called by muse, mutect2, varscan2
- HDAC9 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 144/554 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67769896; called by muse, mutect2, varscan2
- IGKV5-2 | c.172C>T p.Q58* | Nonsense Mutation (SNP) | VAF 102/321 reads (32%) | catalogued as rs1451938889; called by muse, mutect2, varscan2
- IRF8 | c.650G>A p.G217D | Missense Mutation (SNP) | VAF 70/201 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.118); catalogued as COSV51897156; called by muse, mutect2, varscan2
- JAG1 | c.1183G>A p.G395R | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54754995; called by muse, mutect2, varscan2
- KCTD20 | c.68A>G p.D23G | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV54802599; called by muse, mutect2, varscan2
- KPRP | c.1487G>A p.R496H | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); catalogued as rs201034376, COSV64221256, COSV64221349; called by mutect2, varscan2
- LRRC57 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 95/395 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs199784203, COSV52999322; called by muse, mutect2, varscan2
- LRRC66 | c.878G>T p.G293V | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV58632712; called by muse, mutect2, varscan2
- MXRA5 | c.6440G>A p.R2147H | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54229047, COSV54244657; called by muse, mutect2, varscan2
- MYO9B | c.5719C>T p.R1907C | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.921); catalogued as rs190164544, COSV68277904; called by muse, mutect2, varscan2
- MYRF | c.1256C>G p.T419R (on ENST00000278836 / NM_001127392.3; = p.T410R on NM_013279.4) | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53886090, COSV53887127; called by muse, mutect2, varscan2
- NACC2 | c.1399C>T p.R467C | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs940690838, COSV53199274; called by muse, mutect2, varscan2
- NSUN2 | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 101/242 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as rs767166292, COSV52953240; called by muse, mutect2, varscan2
- NSUN5 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV53090955; called by muse, mutect2, varscan2
- OR2W3 | c.379T>G p.C127G | Missense Mutation (SNP) | VAF 56/178 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV64456392; called by muse, mutect2
- OR52N2 | c.839C>G p.A280G | Missense Mutation (SNP) | VAF 83/251 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV57676401; called by muse, mutect2, varscan2
- OTOA | c.1070C>T p.A357V (on ENST00000286149; = p.A343V on NM_144672.4) | Missense Mutation (SNP) | VAF 121/304 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.521); catalogued as COSV53751308; called by muse, mutect2, varscan2
- PCDHGA1 | c.1753G>A p.G585S | Missense Mutation (SNP) | VAF 79/225 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); catalogued as COSV65295584; called by muse, mutect2, varscan2
- PGM5 | c.1417G>A p.V473M | Missense Mutation (SNP) | VAF 53/155 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs781901814, COSV67167136; called by muse, mutect2, varscan2
- PHLPP1 | c.4018C>T p.R1340C | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53025042; called by muse, mutect2, varscan2
- PLEKHM2 | c.305A>G p.N102S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.134); catalogued as rs1391987777, COSV65395609; called by muse, mutect2, varscan2
- PRKG2 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 71/214 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs199612321, COSV52334969; called by muse, mutect2, varscan2
- RB1CC1 | c.2096C>T p.T699M | Missense Mutation (SNP) | VAF 101/272 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs751619561, COSV50244020; called by muse, mutect2, varscan2
- RECQL4 | c.3316C>T p.R1106C | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs770193726, COSV56740142; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RIMS2 | c.4129A>T p.M1377L (on ENST00000666250 / NM_001348490.2; = p.M948L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 99/278 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.223); catalogued as COSV51664997; called by muse, mutect2, varscan2
- TPH1 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 66/310 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754612963, COSV51457439; called by muse, mutect2, varscan2
- TPO | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 127/344 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.668); catalogued as rs139312937; called by muse, mutect2, varscan2
- TXNRD1 | c.431G>A p.R144K (on ENST00000525566 / NM_001093771.3; = p.R46K on NM_003330.4) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61597897; called by muse, mutect2, varscan2
- UTP15 | c.616G>T p.G206W | Missense Mutation (SNP) | VAF 97/247 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99707119; called by muse, mutect2, varscan2
- UTP15 | c.617G>A p.G206E | Missense Mutation (SNP) | VAF 97/247 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1341867792, COSV99707121; called by muse, mutect2, varscan2
- VPS45 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 75/194 reads (39%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as rs370166172; called by muse, mutect2, varscan2
- ZSWIM5 | c.1603T>C p.W535R | Missense Mutation (SNP) | VAF 67/310 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62733240; called by muse, mutect2, varscan2
- IBTK | c.2082_2085del p.S695Rfs*22 | Frame Shift Del (DEL) | VAF 82/266 reads (31%) | called by mutect2, pindel, varscan2
- OR2A5 | c.865dup p.I289Nfs*3 | Frame Shift Ins (INS) | VAF 99/367 reads (27%) | called by mutect2, pindel, varscan2
- SPAG5 | c.2760_2764del p.F921Gfs*10 | Frame Shift Del (DEL) | VAF 46/124 reads (37%) | called by mutect2, pindel, varscan2
- BNC2 | c.2349C>T p.Y783= | Silent (SNP) | VAF 76/182 reads (42%) | catalogued as rs371557826; called by muse, mutect2, varscan2
- BTN1A1 | c.1099A>C p.R367= | Silent (SNP) | VAF 14/358 reads (4%) | catalogued as COSV55067028; called by muse, mutect2
- CNTNAP2 | c.3360C>T p.H1120= | Silent (SNP) | VAF 40/154 reads (26%) | catalogued as rs563414260, COSV62149566; ClinVar: likely benign; called by muse, mutect2
- CRTC1 | c.834C>T p.T278= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs140237275; called by muse, mutect2
- ESPL1 | c.963C>T p.V321= | Silent (SNP) | VAF 45/152 reads (30%) | catalogued as rs200510757, COSV57758257; called by muse, mutect2, varscan2
- MMEL1 | c.1992C>T p.D664= | Silent (SNP) | VAF 55/112 reads (49%) | catalogued as rs537491579, COSV56519616; called by muse, mutect2, varscan2
- PANX2 | c.798C>T p.D266= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as rs35622534; called by mutect2, varscan2
- RIMS2 | c.1512C>T p.G504= (on ENST00000666250 / NM_001348490.2; = p.G312= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 47/113 reads (42%) | catalogued as rs758569920, COSV51656297; called by muse, mutect2, varscan2
- SCN4B | c.255G>A p.K85= | Silent (SNP) | VAF 91/332 reads (27%) | catalogued as COSV61252090, COSV61252134; called by muse, mutect2, varscan2
- SLC6A18 | c.1612C>T p.L538= | Silent (SNP) | VAF 49/133 reads (37%) | catalogued as COSV57250220; called by muse, mutect2, varscan2
- TFAP2D | c.1302C>T p.P434= | Silent (SNP) | VAF 30/93 reads (32%) | catalogued as rs751952833, COSV50410897; called by muse, mutect2, varscan2
- TMC3 | c.2427C>T p.V809= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as COSV63922593; called by muse, mutect2, varscan2
- TMEM25 | c.891C>T p.S297= | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as COSV57096363; called by muse, varscan2
- TTN | c.67848T>C p.Y22616= (on ENST00000591111; = p.Y15192= on NM_003319.4) | Silent (SNP) | VAF 25/163 reads (15%) | catalogued as COSV59951082; called by muse, mutect2, varscan2
